Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A8BT, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A8BT-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:
Right axillary sarcoma.

Specimens Submitted:
1: Right axillary mass

DIAGNOSIS:

1. Right axilla; soft tissue, excision and lymph node dissection:
- High grade spindle and pleomorphic sarcoma compatible with a malignant fibrous histiocytoma.
- Tumor size: 9.5 x 8.4 x 4.1 cm.
- Unremarkable skin and subcutaneous tissue with fat necrosis.
- The tumor extends focally to an inked undesignated margin.
- Ten benign lymph nodes (0/10).

Note: Immunohistochemical stains show tumor cells are negative for MDM2, CDK4, AE1:AE3 and 34BE12.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). Received fresh labeled "right axillary mass" is a 19 x 10 x 5 cm specimen consisting of a mass with overlying axillary fat, subcutaneous tissue, and a skin ellipse. The margins are inked black. The mass is 9.5 x 8.4 x 4.1 cm and has a variegated tan yellow cut surface. Focal areas appear necrotic and hemorrhagic. The mass abuts the surgical margins, however, appears to be contained within a thin fibrous membrane. For the most part the mass is well-circumscribed with the exception of the superficial aspect which has an irregular infiltrating appearing border. Within the axillary fat there are multiple lymph nodes ranging from 0.8 to 2.9 cm in greatest diameter. Representative sections are submitted for permanent sections and

** Continued on next page **

ICD-O-3
Histiocytoma, fibrous malignant
883613
Site: (R) Axilla NOS
C49.3
J11/22/13

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2

TPS. Photographs are taken.

Summary of sections:

M - margins
T - tumor
TF - tumor edge of selling to infiltrate into fat
LN - lymph nodes
BLN - bisected lymph node

Summary of Sections:

Part 1: Right axillary mass

Block	Sect.	Site	PCs
5		BLN	8
3		LN	3
5		M	5
1		SK	1
4		T	4
2		TF	2

** End of Report **

TPAA Discrepancy		✓
Primary Tumor History		✓
Qual/Synchroniz. Primary Noted		✓

Source: NCI Genomic Data Commons file f6479380-4e31-420f-b945-aa1caa3dd910 (TCGA-DX-A8BT.3D75F168-83E4-42B1-AEAA-3DC19B04AA76.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).